Somatic mutation profile of tumor specimen TCGA-BP-4999-01A (aliquot TCGA-BP-4999-01A-01D-1462-08) from TCGA case TCGA-BP-4999, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.2 years (20,518 days).
Specimen TCGA-BP-4999-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6fc6df1-89cc-47a8-923b-58b34500bef1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4999-11A (Solid Tissue Normal), aliquot TCGA-BP-4999-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97fdee6c-3e5e-4cbd-a604-fca39343217d

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 4, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs869025621, CM130353, CM130970, CM941365, COSV56545109, COSV56549825, COSV56558459; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.7988A>G p.K2663R | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV52513832; called by muse, mutect2, varscan2
- APBB2 | c.1654C>T p.R552W (on ENST00000295974 / NM_001166050.2; = p.R553W on NM_004307.2) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs776253380, COSV55951872; called by muse, mutect2, varscan2
- APOH | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs934439825, COSV52773455; called by muse, mutect2, varscan2
- CCT6B | c.770A>T p.E257V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV58490119; called by muse, mutect2, varscan2
- CLPTM1L | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as rs757419542, COSV57990685; called by muse, mutect2
- EIF4G2 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV60598108; called by muse, mutect2, varscan2
- GPNMB | c.1253G>A p.G418E (on ENST00000381990 / NM_001005340.2; = p.G406E on NM_002510.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51699366; called by muse, mutect2, varscan2
- HHEX | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51106643; called by muse, mutect2, varscan2
- HHIPL2 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV58566027; called by muse, mutect2, varscan2
- HLA-DPA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs770307009, COSV70089438; called by muse, mutect2, varscan2
- INPPL1 | c.3160C>G p.P1054A | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.355); catalogued as rs374103936; called by muse, mutect2, varscan2
- KRT24 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52880842; called by muse, mutect2, varscan2
- MAGEA4 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as COSV52342139; called by muse, mutect2, varscan2
- MICALL2 | c.2627T>C p.I876T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs747537069, COSV52516790; called by muse, mutect2, varscan2
- MUC16 | c.17150A>C p.N5717T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.192); catalogued as COSV67476958; called by muse, mutect2, varscan2
- MYO6 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64119875, COSV64121461; called by muse, mutect2, varscan2
- MZF1 | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV53042130; called by muse, mutect2
- NSUN2 | c.2083C>G p.R695G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); catalogued as COSV52955436; called by muse, mutect2, varscan2
- OR10G3 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57810661; called by muse, mutect2, varscan2
- PDS5B | c.29A>C p.D10A | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59729743; called by muse, mutect2, varscan2
- PDS5B | c.2505G>A p.W835* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV59729746; called by muse, mutect2, varscan2
- PYGB | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53820178; called by muse, mutect2, varscan2
- RCC2 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64906051; called by muse, mutect2
- RDH11 | c.714A>T p.E238D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV67282943; called by muse, mutect2, varscan2
- TEKT2 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52881357; called by muse, mutect2, varscan2
- TMEM59L | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1233076706, COSV53242551, COSV53242742; called by muse, mutect2, varscan2
- TPR | c.2129A>G p.Q710R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.366); catalogued as COSV66602669; called by muse, mutect2, varscan2
- ZFYVE19 | c.995G>T p.R332L (on ENST00000355341 / NM_001077268.2; = p.R322L on NM_032850.5) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs952202122, COSV54541038; called by muse, mutect2, varscan2
- ZNF607 | c.480T>A p.H160Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62205664; called by muse, mutect2, varscan2
- COG1 | c.1713del p.T572Lfs*57 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- DNMT3A | c.1848del p.E616Dfs*35 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ESYT2 | c.1222del p.V408Sfs*38 (on ENST00000613624; = p.V332Sfs*38 on NM_020728.3) | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- RAB21 | c.277_279del p.N93del | In Frame Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- RP1 | c.3249_3254del p.L1083_V1085delinsF | In Frame Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- USP33 | c.2520del p.E841Rfs*22 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2525G>A p.C842Y | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CD84 | c.576G>A p.T192= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs770096210, COSV60869194; called by muse, mutect2, varscan2
- IGHV3-20 | c.105G>T p.G35= | Silent (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- MYH9 | c.3141G>A p.E1047= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV53389000; called by muse, mutect2, varscan2
- PRDM12 | c.450C>A p.I150= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV53391020, COSV99446416; called by muse, mutect2, varscan2
- RELL2 | c.645G>A p.G215= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1487509577, COSV51837879, COSV99781138; called by muse, mutect2, varscan2
- RFX7 | c.789T>C p.V263= (on ENST00000559447 / NM_001368074.1; = p.V360= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57965834; called by muse, mutect2, varscan2
- SETD1A | c.2175C>G p.A725= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV52689635; called by muse, mutect2, varscan2
- SSX2IP | c.1452C>A p.T484= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs1439510324, COSV60553509; called by muse, mutect2, varscan2
- THY1 | c.162G>C p.L54= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV52454709; called by muse, mutect2, varscan2
- TMBIM1 | c.801C>T p.Y267= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs377618088; called by mutect2, varscan2
- ZC3H7A | c.174T>C p.D58= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs770771373, COSV63270269; called by muse, mutect2, varscan2
- ZFAND2B | c.696G>A p.L232= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs1385135599, COSV54697446; called by muse, mutect2, varscan2
